Somatic mutation profile of tumor specimen TCGA-AK-3451-01A (aliquot TCGA-AK-3451-01A-02D-1251-10) from TCGA case TCGA-AK-3451, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage II; Tumor grade: G3; Age at diagnosis: 48.9 years (17,859 days).
Specimen TCGA-AK-3451-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8e82f04b-b3f6-4e73-8b6f-ccbce085a636.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AK-3451-10A (Blood Derived Normal), aliquot TCGA-AK-3451-10A-01D-1251-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9fcd6f48-6219-4a11-bffc-9d6b843e5130

The open-access MAF lists 82 somatic variants for this specimen: 70 protein-altering or splice-affecting, 8 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 55, Silent 8, Frame Shift Del 8, In Frame Del 3, Nonsense Mutation 2, Intron 2, Frame Shift Ins 1, In Frame Ins 1, 3'Flank 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HOOK3 | c.1150G>A p.E384K | Missense Mutation (SNP) | VAF 88/400 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.36); catalogued as rs747141054, COSV56879174; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCG4 | c.1684C>A p.L562M | Missense Mutation (SNP) | VAF 46/237 reads (19%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.688); catalogued as COSV56644435; called by muse, mutect2, varscan2
- AFAP1L2 | c.340A>C p.I114L | Missense Mutation (SNP) | VAF 68/283 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58416332; called by muse, mutect2, varscan2
- AFF4 | c.229A>G p.I77V | Missense Mutation (SNP) | VAF 265/649 reads (41%) | SIFT tolerated (0.21); PolyPhen benign (0.043); catalogued as rs372069594; called by muse, mutect2, varscan2
- BAP1 | c.224A>G p.D75G | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.013); catalogued as COSV56232999, COSV99963558; called by muse, mutect2, varscan2
- CAND1 | c.2623G>A p.A875T | Missense Mutation (SNP) | VAF 82/348 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV73389684; called by muse, mutect2, varscan2
- CAPZA2 | c.709A>T p.N237Y | Missense Mutation (SNP) | VAF 71/255 reads (28%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.934); catalogued as COSV63267009; called by muse, mutect2, varscan2
- CARD11 | c.2818C>G p.L940V | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT tolerated (0.29); PolyPhen benign (0.009); catalogued as COSV62755943; called by muse, mutect2, varscan2
- CHD3 | c.3303C>A p.Y1101* | Nonsense Mutation (SNP) | VAF 96/364 reads (26%) | catalogued as COSV57875664; called by muse, mutect2, varscan2
- CLEC9A | c.537G>C p.Q179H | Missense Mutation (SNP) | VAF 132/573 reads (23%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.981); catalogued as COSV59532860; called by muse, mutect2, varscan2
- CTNND2 | c.3031C>A p.Q1011K | Missense Mutation (SNP) | VAF 101/341 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as COSV58904144; called by muse, mutect2, varscan2
- CYP4A11 | c.456T>G p.Y152* | Nonsense Mutation (SNP) | VAF 14/84 reads (17%) | catalogued as COSV60224292; called by muse, mutect2, varscan2
- DDC | c.36G>C p.E12D | Missense Mutation (SNP) | VAF 73/257 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.001); catalogued as COSV63566142; called by muse, mutect2, varscan2
- DPPA2 | c.112del p.E38Nfs*72 | Frame Shift Del (DEL) | VAF 115/479 reads (24%) | catalogued as COSV72117935; called by mutect2, pindel, varscan2
- DYRK2 | c.1669A>C p.T557P (on ENST00000344096 / NM_006482.3; = p.T484P on NM_003583.4) | Missense Mutation (SNP) | VAF 31/103 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.06); catalogued as COSV59846797; called by muse, mutect2, varscan2
- EVI5 | c.1735G>A p.E579K | Missense Mutation (SNP) | VAF 224/892 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.14); catalogued as COSV64828398; called by muse, mutect2, varscan2
- EWSR1 | c.53A>G p.Y18C | Missense Mutation (SNP) | VAF 265/881 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as rs1035042314, COSV53323823; called by muse, mutect2, varscan2
- FAM71F1 | c.467T>C p.V156A | Missense Mutation (SNP) | VAF 68/283 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.389); catalogued as COSV59374173; called by muse, mutect2, varscan2
- GABRG2 | c.539A>G p.Y180C | Missense Mutation (SNP) | VAF 53/267 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62719697; called by muse, mutect2, varscan2
- GALNT5 | c.191G>A p.G64E | Missense Mutation (SNP) | VAF 72/286 reads (25%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs772190687, COSV52039086; called by muse, mutect2, varscan2
- IGF2R | c.2213G>A p.G738D | Missense Mutation (SNP) | VAF 44/127 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV63630579; called by muse, mutect2, varscan2
- KCNT2 | c.2813G>T p.R938I | Missense Mutation (SNP) | VAF 121/473 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.726); catalogued as COSV54090537; called by muse, mutect2, varscan2
- KDM4D | c.263A>G p.Q88R | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58635298; called by muse, mutect2
- KIF20B | c.338T>G p.F113C | Missense Mutation (SNP) | VAF 65/261 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53310467; called by muse, mutect2, varscan2
- MBD6 | c.2239G>T p.D747Y | Missense Mutation (SNP) | VAF 32/87 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV100851726, COSV63075463; called by muse, mutect2, varscan2
- MED14 | c.1282A>C p.N428H | Missense Mutation (SNP) | VAF 79/140 reads (56%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.73); catalogued as COSV61357601; called by muse, mutect2, varscan2
- MME | c.850G>T p.A284S | Missense Mutation (SNP) | VAF 131/447 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs572687446, COSV64708651; called by muse, mutect2, varscan2
- MME | c.851C>G p.A284G | Missense Mutation (SNP) | VAF 125/434 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64708657; called by muse, mutect2, varscan2
- MTMR12 | c.1169T>C p.L390S | Missense Mutation (SNP) | VAF 167/641 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.183); catalogued as COSV53785619; called by muse, mutect2, varscan2
- NAT1 | c.259A>T p.T87S | Missense Mutation (SNP) | VAF 98/347 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.118); catalogued as COSV56985791; called by muse, mutect2, varscan2
- OR8B12 | c.309C>A p.F103L | Missense Mutation (SNP) | VAF 30/162 reads (19%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.031); catalogued as COSV60912187, COSV60912242; called by muse, mutect2, varscan2
- PKD1 | c.6769G>T p.V2257L | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.914); catalogued as rs780375073, COSV51919875; called by muse, mutect2, varscan2
- PKHD1L1 | c.11485del p.E3829Kfs*14 | Frame Shift Del (DEL) | VAF 60/286 reads (21%) | catalogued as COSV65739135; called by mutect2, pindel*, varscan2
- PRPF19 | c.1475C>T p.S492L | Missense Mutation (SNP) | VAF 24/81 reads (30%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.953); catalogued as COSV57128493; called by muse, varscan2
- PTPRG | c.3229C>G p.L1077V | Missense Mutation (SNP) | VAF 91/281 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV55649461; called by muse, mutect2, varscan2
- RALGAPA2 | c.4567T>G p.L1523V | Missense Mutation (SNP) | VAF 84/306 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as COSV52502641; called by muse, mutect2, varscan2
- RBM23 | c.1023G>T p.E341D (on ENST00000359890 / NM_001077351.2; = p.E325D on NM_018107.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 38/95 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.024); catalogued as COSV57128178; called by muse, mutect2, varscan2
- RFTN1 | c.1199A>G p.Y400C | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs998047684, COSV61920739; called by muse, mutect2, varscan2
- RINL | c.443A>C p.E148A (on ENST00000591812 / NM_001195833.2; = p.E34A on NM_198445.4) | Missense Mutation (SNP) | VAF 57/205 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV61575045; called by muse, mutect2, varscan2
- SCP2 | c.1586T>A p.M529K | Missense Mutation (SNP) | VAF 131/443 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV65261612; called by muse, mutect2, varscan2
- SHOX2 | c.819del p.Y274Tfs*2 (on ENST00000441443 / NM_006884.3; = p.Y298Tfs*2 on NM_003030.4) | Frame Shift Del (DEL) | VAF 10/39 reads (26%) | catalogued as COSV67464593; called by mutect2, pindel, varscan2
- SLC18A3 | c.371T>G p.I124S | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV60328169; called by muse, mutect2, varscan2
- SPC25 | c.158A>C p.E53A | Missense Mutation (SNP) | VAF 148/688 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV56370504; called by muse, mutect2, varscan2
- SPHKAP | c.1930A>G p.N644D | Missense Mutation (SNP) | VAF 58/220 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.157); catalogued as COSV60885189; called by muse, mutect2, varscan2
- SRSF11 | c.238T>G p.F80V | Missense Mutation (SNP) | VAF 98/386 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.5); catalogued as COSV63937302; called by muse, mutect2
- STX2 | c.58G>C p.V20L | Missense Mutation (SNP) | VAF 97/365 reads (27%) | SIFT tolerated (0.15); PolyPhen benign (0.011); catalogued as COSV55434831; called by muse, mutect2, varscan2
- SYTL5 | c.2013C>A p.N671K | Missense Mutation (SNP) | VAF 84/160 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as COSV52902877; called by muse, mutect2, varscan2
- TMEM243 | c.272T>A p.F91Y | Missense Mutation (SNP) | VAF 124/452 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV57538839; called by muse, mutect2, varscan2
- TSGA10 | c.205G>A p.E69K | Missense Mutation (SNP) | VAF 110/404 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.097); catalogued as COSV61824135; called by muse, mutect2, varscan2
- TSPAN32 | c.299T>A p.L100Q | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51720779; called by muse, mutect2, varscan2
- TTN | c.24383C>T p.A8128V (on ENST00000591111; = p.A7201V on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 56/229 reads (24%) | PolyPhen possibly damaging (0.803); catalogued as COSV60172167; called by muse, mutect2, varscan2
- UGT1A7 | c.559C>G p.L187V | Missense Mutation (SNP) | VAF 69/277 reads (25%) | SIFT tolerated (0.37); PolyPhen benign (0.052); catalogued as COSV60843734; called by muse, varscan2
- URB2 | c.3005G>A p.G1002E | Missense Mutation (SNP) | VAF 69/283 reads (24%) | SIFT tolerated (0.85); PolyPhen benign (0.014); catalogued as COSV51002507; called by muse, mutect2, varscan2
- VWA8 | c.4015C>A p.Q1339K | Missense Mutation (SNP) | VAF 111/467 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.15); catalogued as COSV64998063; called by muse, mutect2, varscan2
- XIRP2 | c.151G>T p.V51L | Missense Mutation (SNP) | VAF 42/141 reads (30%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0); catalogued as COSV54713556; called by muse, mutect2, varscan2
- ZDHHC5 | c.36C>A p.S12R | Missense Mutation (SNP) | VAF 54/231 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV54707786; called by muse, mutect2, varscan2
- ZNF224 | c.611A>G p.Y204C | Missense Mutation (SNP) | VAF 33/190 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.041); catalogued as rs776173519, COSV61242739; called by muse, mutect2, varscan2
- ZNF235 | c.1459T>A p.Y487N | Missense Mutation (SNP) | VAF 88/292 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52157347; called by muse, mutect2, varscan2
- ZNF641 | c.926G>A p.R309K | Missense Mutation (SNP) | VAF 71/262 reads (27%) | SIFT tolerated (0.49); PolyPhen benign (0.34); catalogued as COSV56390888; called by muse, mutect2, varscan2
- ADAMTS1 | c.1288_1290del p.M430del | In Frame Del (DEL) | VAF 41/202 reads (20%) | called by pindel, varscan2
- AOX1 | c.3624del p.F1208Lfs*10 | Frame Shift Del (DEL) | VAF 138/543 reads (25%) | called by mutect2, pindel, varscan2
- CDH19 | c.1149_1151del p.P384del | In Frame Del (DEL) | VAF 44/194 reads (23%) | called by mutect2, pindel, varscan2
- FBLN2 | c.1090_1094del p.K364Cfs*30 | Frame Shift Del (DEL) | VAF 6/14 reads (43%) | called by mutect2, varscan2
- GEMIN5 | c.2246del p.L749* | Frame Shift Del (DEL) | VAF 139/801 reads (17%) | called by mutect2, pindel*, varscan2*
- JARID2 | c.3142_3150dup p.K1048_R1050dup | In Frame Ins (INS) | VAF 20/96 reads (21%) | called by mutect2, varscan2
- KMT2C | c.4110del p.D1371Ifs*3 | Frame Shift Del (DEL) | VAF 58/254 reads (23%) | called by mutect2, pindel, varscan2
- LRRC8D | c.1673del p.L558Cfs*10 | Frame Shift Del (DEL) | VAF 29/102 reads (28%) | called by mutect2, pindel, varscan2
- MST1R | c.567_575del p.E190_G192del | In Frame Del (DEL) | VAF 4/8 reads (50%) | called by mutect2, varscan2
- MUC2 | c.1343C>T p.S448F | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT deleterious (0); called by muse, mutect2, varscan2
- NEK10 | c.1468_1469dup p.L490Ffs*3 | Frame Shift Ins (INS) | VAF 106/332 reads (32%) | called by mutect2, pindel, varscan2
- CCDC40 | c.2067C>T p.D689= | Silent (SNP) | VAF 16/109 reads (15%) | catalogued as rs765374707, COSV66476309; called by muse, mutect2, varscan2
- FAM183A | c.189A>C p.A63= | Silent (SNP) | VAF 68/382 reads (18%) | catalogued as COSV58922593; called by muse, mutect2
- KIF21B | c.2448C>A p.T816= | Silent (SNP) | VAF 19/51 reads (37%) | catalogued as COSV59760994; called by muse, mutect2, varscan2
- PIAS1 | c.867C>T p.S289= | Silent (SNP) | VAF 144/538 reads (27%) | catalogued as COSV51034029; called by muse, varscan2
- PKD1 | c.6768G>T p.L2256= | Silent (SNP) | VAF 10/26 reads (38%) | catalogued as COSV51919885; called by muse, mutect2, varscan2
- PTPRM | c.2070T>A p.T690= | Silent (SNP) | VAF 48/180 reads (27%) | catalogued as COSV59868654; called by muse, mutect2, varscan2
- SEMA4F | c.1008G>T p.G336= | Silent (SNP) | VAF 21/85 reads (25%) | catalogued as COSV60284098; called by muse, mutect2, varscan2
- ZMYM1 | c.1536G>A p.K512= | Silent (SNP) | VAF 38/164 reads (23%) | catalogued as COSV63252465, COSV63252586; called by muse, mutect2, varscan2
- CFAP65 | c.542+138A>C | Intron (SNP) | VAF 49/178 reads (28%) | catalogued as COSV55390879; called by muse, mutect2, varscan2
- HOXC10 | chr12:53991812 C>T | 3'Flank (SNP) | VAF 64/181 reads (35%) | catalogued as COSV57726664; called by muse, mutect2, varscan2
- KARS1 | c.63-2627C>T | Intron (SNP) | VAF 41/127 reads (32%) | catalogued as COSV55613668; called by muse, mutect2, varscan2
- MIR520D | n.80G>T | RNA (SNP) | VAF 55/262 reads (21%) | called by muse, mutect2, varscan2
